Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8HJ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8HJ-01A (Primary Tumor).

[page 1 of 2]
PROSTATE AND PELVIC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN 3

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

Not described

TUMOR LOCATION

APEX

MID

BASE

ANTERIOR

RIGHT

LATERAL

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

Not determined

SEMINAL VESICAL INVASION

PRESENT

RIGHT

SURGICAL MARGINS

FREE OF INVASIVE CARCINOMA

LYMPHOVASCULAR INVASION

PRESENT

PERINEURAL INVASION

Not described

TUMOR VOLUME/size of the largest nodule

1.6x3x2.8cm=13.44cc

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

NO LYMPH NODES SUBMITTED

NO LYMPH NODES IDENTIFIED

PATHOLOGICAL STAGING

pT3b

pNX

pMX

*COMMENT(S)

Presence of a Ductal component of 25-30%

ICD-O-3

Adenocarcinoma, acinar 8140/3

Site: Prostate NOS C61.9

9/11/29/13

Criteria	11/12/13	11/16	Yes	11/16

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Acinar Adenocarcinoma, Gleason 4+5=9 with Ductal component	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Acinar Adenocarcinoma, Gleason 4+5=9	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	provided sample does not include Ductal component (Sampling Issue)	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director _____

Date _____

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature _____

Date _____

Source: NCI Genomic Data Commons file a782476f-8721-4ffa-b41a-b9b1f8f18d07 (TCGA-YL-A8HJ.A4B8AFC5-774E-4FB2-8191-735949EC3E42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).